TARGET case TARGET-40-NAAHCD — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/28e8157e-943a-5c5d-bcf4-ddc9afea5d4c

Demographics
Sex at birth: female; Age at index: 15 years; Vital status: Dead; Days to death: 199 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 15.4 years (5,612 days); Year of diagnosis: 2002; Metastasis at diagnosis: No Metastasis; Days to last follow up: 199 days.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 167 days; Progression or recurrence: Yes; Days to progression: 167 days; Days to first event: 167 days; First event: Relapse.
- Days to follow up: 199 days; Year of follow up: 2003.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHCD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 199
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Site of initial relapse: Non-bone, non-lung
- Percent necrosis at Definitive Surgery: <30
